Somatic mutation profile of tumor specimen 0DOJXV from CCDI case PBCCSD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,069 days).
Specimen 0DOJXV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35f15825-8029-4206-a8b6-2ea2021f2a65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOJUX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c79c5b00-aab8-4110-98b2-0fae80053641

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1, Intron 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F8 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 102/1002 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs781217568, COSV100358087; called by muse, mutect2
- CDH10 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 134/1640 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- HEPH | c.1459G>T p.V487F (on ENST00000343002; = p.V220F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/495 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IL11 | c.492del p.S165Pfs*19 | Frame Shift Del (DEL) | VAF 52/346 reads (15%) | called by mutect2, varscan2
- MUC16 | c.40650C>G p.I13550M | Missense Mutation (SNP) | VAF 105/537 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HDAC5 | c.2945-50A>T | Intron (SNP) | VAF 55/168 reads (33%) | catalogued as rs1343683207; called by muse, mutect2, varscan2
- PRR9 | c.*29G>C | 3'UTR (SNP) | VAF 18/212 reads (8%) | catalogued as rs1034356356; called by muse, mutect2, varscan2
- TAF1 | c.-26C>T | 5'UTR (SNP) | VAF 115/323 reads (36%) | catalogued as rs749083988; called by muse, mutect2, varscan2
